Gene-level copy-number profile of tumor specimen TCGA-38-4628-01A from TCGA case TCGA-38-4628, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIB; Age at diagnosis: 65.9 years (24,057 days).
Specimen TCGA-38-4628-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUAD.03493379-b8b3-4398-9a53-0513c970eeda.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-38-4628-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 806 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/fd046d02-4335-4716-b1f3-0beba185a33a

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 102; copy number 2: 1,315; copy number 3: 8,143; copy number 4: 15,776; copy number 5: 8,840; copy number 6: 11,576; copy number 7: 7,308; copy number 8: 2,853; copy number 9: 3,023; copy number 10: 272; copy number 11: 87; copy number 12: 166; copy number 17: 5; copy number 20: 122; copy number 25: 47; copy number 27: 4; copy number 28: 36; copy number 44: 142.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-38-4628-01A-01D-1204-01): tumor purity 0.5, ploidy 4.98, whole-genome doublings 2.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 3,899 genes in 36 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:35,569,813–37,474,411, 44 genes, copy number 12 (within-gene range 6–12): TFAP2E-AS1, TFAP2E, PSMB2, C1orf216, CLSPN, AL354864.1, AGO4, AGO1, CFAP97P1, AL139286.2, AL139286.1, AGO3, AL138787.2, AL138787.1, TEKT2, ADPRS, COL8A2, TRAPPC3, MAP7D1, RN7SL131P, THRAP3, UBE2V2P4, SH3D21, EVA1B, AL591845.1, STK40, LSM10, RNU4-27P, OSCP1, SNORA63C, MRPS15, CSF3R, FTLP18, AL596257.1, AC117945.2, AC117945.1, GRIK3, AL031430.1, AL353604.1, MIR4255, RNU6-636P, RNA5SP43, RPS29P6, LINC01137.
- chr1:63,139,250–64,833,232, 37 genes, copy number 9: AC096543.1, LINC00466, RNA5SP49, AC096543.2, RPSAP65, FOXD3-AS1, FOXD3, MIR6068, Y_RNA, AL049636.1, ALG6, ITGB3BP, BX004807.1, EFCAB7, RN7SL488P, RNU7-123P, DLEU2L, AL109925.3, AL109925.6, AL109925.4, AL109925.2, AL109925.5, AL109925.1, PGM1, RN7SL130P, ROR1, AL161742.1, CFL1P3, RNU6-809P, Y_RNA, ROR1-AS1, AL445205.1, UBE2U, RNU7-62P, CACHD1, MIR4794, RAVER2.
- chr1:143,343,180–175,922,145, 1,137 genes, copy number 9 (broad region; genes not listed).
- chr1:178,725,147–178,921,841, 1 gene, copy number 9 (within-gene range 4–9): RALGPS2.
- chr1:178,849,535–199,021,037, 282 genes, copy number 9 (within-gene range 7–9) (broad region; genes not listed).
- chr4:49,096–9,755,778, 284 genes, copy number 9 (broad region; genes not listed).
- chr5:36,876,769–37,066,413, 1 gene, copy number 9 (within-gene range 7–9): NIPBL.
- chr5:37,085,056–45,696,498, 141 genes, copy number 9 (broad region; genes not listed).
- chr7:70,972–11,832,198, 230 genes, copy number 9 (within-gene range 8–9) (broad region; genes not listed).
- chr7:12,469,621–19,773,617, 80 genes, copy number 9 (within-gene range 8–9) (broad region; genes not listed).
- chr7:40,135,005–40,860,763, 1 gene, copy number 9 (within-gene range 8–9): SUGCT.
- chr7:40,538,127–57,837,046, 353 genes, copy number 9 (broad region; genes not listed).
- chr7:142,855,061–143,836,933, 51 genes, copy number 9: EPHB6, TRPV6, AC245427.1, AC245427.2, TRPV5, LLCFC1, KEL, OR9A2, OR9P1P, OR6V1, OR6W1P, PIP, TAS2R39, AC073342.1, TAS2R40, AC073342.2, GSTK1, TMEM139-AS1, TMEM139, CASP2, RN7SL535P, RN7SL481P, HINT1P1, CLCN1, FAM131B, AC093673.2, AC093673.1, ZYX, MIR6892, EPHA1, EPHA1-AS1, TAS2R62P, TAS2R60, TAS2R41, OR2R1P, OR10AC1, AC073264.1, PAICSP5, CTAGE15, RNU6-162P, AC073264.2, TCAF1P1, AC073264.3, TCAF2, TCAF2C, RNU6-267P, CTAGE6, AC099548.2, PAICSP6, AC099548.1, TCAF2P1.
- chr7:144,451,941–148,420,998, 19 genes, copy number 10 (within-gene range 6–10): TPK1, EEF1A1P10, RN7SKP174, EI24P4, AC073310.1, RPL7P59, AC004911.1, DPY19L4P2, AC006007.1, AC073308.1, CNTNAP2, AC073418.1, Y_RNA, CNTNAP2-AS1, DUTP3, RANP2, MIR548F4, AC005518.1, AC005518.2.
- chr7:157,138,916–159,233,377, 32 genes, copy number 10 (within-gene range 6–10): UBE3C, RPS27AP12, AC004898.1, AC004975.1, AC004975.2, DNAJB6, AC006372.3, AC006372.1, AC006372.2, AC006372.4, PTPRN2, MIR153-2, AC005481.1, AC006003.1, PTPRN2-AS1, AC011899.2, AC011899.3, AC011899.1, MIR595, AC078942.1, LINC01022, MIR5707, THAP5P1, NCAPG2, AC019084.1, ESYT2, DYNC2I1, AC004863.1, LINC00689, VIPR2, AC007269.1, PIP5K1P2.
- chr8:33,604,856–34,039,104, 1 gene, copy number 10 (within-gene range 3–10): AF279873.3.
- chr8:33,715,784–46,028,892, 205 genes, copy number 9–11 (broad region; genes not listed).
- chr8:51,015,021–53,390,872, 26 genes, copy number 9: AC090919.1, AC012413.1, PXDNL, BRIX1P1, BTF3P1, AC090186.1, PCMTD1, AC103769.1, AC064807.1, AC064807.4, AC064807.2, AC064807.3, ST18, AC021915.2, AC021915.1, AC103831.1, RPL34P17, ALKAL1, RB1CC1, AC113139.1, NPBWR1, AC009800.1, AC009646.1, AC009646.2, OPRK1, AC131902.1.
- chr8:53,394,215–53,394,795, 1 gene, copy number 9: AC131902.2.
- chr8:56,160,909–59,137,502, 49 genes, copy number 10 (within-gene range 7–10): PLAG1, CHCHD7, AC107952.2, AC107952.1, SDR16C5, SDR16C6P, PENK, AC012349.1, SEPTIN10P1, LINC00968, AC013644.1, RPL37P6, AC009597.1, AC009597.2, RNU6-13P, BPNT2, RNA5SP266, LINC01606, AC025674.1, AC025674.2, LINC00588, RNU6-596P, AC068075.1, RPL30P10, AC068075.2, AC090796.1, AC104051.1, AC104051.2, LINC01602, AC012103.1, FAM110B, AC104350.1, AC027698.1, RPL26P26, AC092819.3, AC092819.1, AC092819.2, UBXN2B, AC009927.1, CYP7A1, PPIAP85, SDCBP, NSMAF, AC068522.1, TOX, RNU4-50P, AC105150.1, AC090152.1, AC087698.1.
- chr11:29,335,878–29,989,328, 1 gene, copy number 9 (within-gene range 6–9): LINC02755.
- chr11:29,482,807–33,033,582, 52 genes, copy number 9: AC110058.1, LINC02546, HNRNPRP2, AC107973.1, RN7SL240P, RPL7AP58, LINC01616, KCNA4, AL358944.1, AL358944.2, FSHB, ARL14EP, RPL12P30, MPPED2, AL353699.1, MPPED2-AS1, AL122014.1, DCDC1, CYCSP25, AL137804.1, DNAJC24, IMMP1L, ELP4, AC131571.1, PAX6, PAUPAR, AL035078.4, AL035078.1, AL035078.3, AL035078.2, U3, EIF4A2P5, RCN1, AL078612.1, THEM7P, AL078612.2, WT1, WT1-AS, AL049692.6, AL049692.1, AL049692.5, AL049692.3, AL049692.2, AL049692.4, EIF3M, HNRNPA3P9, CCDC73, AL049714.1, PRRG4, QSER1, Y_RNA, DEPDC7.
- chr11:35,943,981–36,232,136, 1 gene, copy number 9 (within-gene range 7–9): LDLRAD3.
- chr11:36,010,098–36,697,867, 13 genes, copy number 9: MIR3973, AC129502.1, COMMD9, PRR5L, AC087277.1, AC087277.2, AC009656.1, TRAF6, AC061999.1, RAG1, RAG2, IFTAP, AC104042.1.
- chr11:69,641,156–69,819,416, 6 genes, copy number 9: CCND1, LTO1, FGF19, DNAJB6P5, FGF4, FGF3.
- chr11:77,066,961–79,989,630, 53 genes, copy number 10: CAPN5, OMP, MYO7A, GDPD4, TOMM20P1, PAK1, AP003680.1, CLNS1A, RNU7-59P, AQP11, RSF1, Y_RNA, RSF1-IT2, FTH1P16, RSF1-IT1, AP000580.1, AAMDC, AP002812.2, AP002812.3, AP002812.5, AP002812.1, INTS4, AP002812.4, AP003032.2, KCTD14, NDUFC2-KCTD14, AP003032.1, THRSP, NDUFC2, ALG8, RNU6-126P, KCTD21-AS1, KCTD21, USP35, GAB2, AP002985.1, AP003086.1, AP003086.3, AP003086.2, LINC02728, NARS2, AP003110.1, RNU6-311P, COPS8P3, TENM4, AP002768.1, AP002957.1, AP001547.1, MIR708, MIR5579, AP001978.1, AP001541.1, AP001284.1.
- chr12:20,695,332–21,657,798, 16 genes, copy number 9 (within-gene range 6–9): SLCO1C1, SLCO1B3, SLCO1B3-SLCO1B7, AC011604.1, SLCO1B7, AC022335.1, SLCO1B1, SLCO1A2, IAPP, PYROXD1, ELOCP31, RECQL, GOLT1B, SPX, GYS2, AC010197.2.
- chr12:56,663,341–65,826,997, 205 genes, copy number 20–28 (within-gene range 4–28) (broad region; genes not listed).
- chr12:66,347,431–75,511,636, 146 genes, copy number 27–44 (within-gene range 4–44) (broad region; genes not listed).
- chr14:31,334,312–40,390,547, 152 genes, copy number 10–12 (within-gene range 8–12) (broad region; genes not listed).
- chr14:71,848,606–72,566,530, 2 genes, copy number 9–10 (within-gene range 4–10): AC005993.1, RGS6.
- chr14:72,515,407–73,633,941, 37 genes, copy number 10 (within-gene range 8–10): AC004828.2, MIR7843, AC004828.1, DPF3, AL392024.1, Y_RNA, DCAF4, AC007160.1, AL442663.4, AL442663.1, ZFYVE1, RN7SL586P, AL442663.3, RBM25, AL442663.2, PSEN1, AC004858.1, PAPLN, AC004846.1, RNU6-419P, AC004846.2, NUMB, AC005280.3, AC005280.2, AC005280.1, HEATR4, RIOX1, AC005225.1, AC005225.3, ACOT1, NT5CP2, AC005225.2, ACOT2, NT5CP1, AC005225.4, ACOT4, ACOT6.
- chr15:54,048,588–54,050,876, 1 gene, copy number 11: AC010867.1.
- chr18:47,390–4,459,458, 100 genes, copy number 9 (broad region; genes not listed).
- chr20:33,731,657–34,560,345, 31 genes, copy number 10 (within-gene range 6–10): ZNF341, RPL31P2, ZNF341-AS1, CHMP4B, TPM3P2, PIGPP3, RALY-AS1, RALY, AL031668.1, MIR4755, EIF2S2, RPS2P1, AL031668.2, ASIP, XPOTP1, AL035458.2, AL035458.1, AHCY, AL356299.2, AL356299.1, ITCH, Y_RNA, CDC42P1, ITCH-AS1, ITCH-IT1, MIR644A, FDX1P1, AL109923.1, DYNLRB1, Y_RNA, MAP1LC3A.
- chr20:62,575,590–64,313,132, 108 genes, copy number 9 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 102. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
